Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01S, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01S-01A (Primary Tumor).

TCGA #:

Sample ID #:

Diagnosis:

This is an invasive, moderately differentiated adenocarcinoma in the sigmoid colon.
Both resection margins are tumor-free, as is the area of the central vascular ligature.
There is also a lymph node metastasis.

Tumor classification:

ICDO-DA M

8140/3

G 2

p T 3,

p N 1 (1/19),

R 0.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: Sigmoid colon C18.7 /w 3/30/11

PIPPAA Discrepancy		
Case (Circle):		

Source: NCI Genomic Data Commons file cd1c930b-cff0-4d1d-be1a-fb95c306a9c1 (TCGA-AA-A01S.5A447FA7-E561-4F17-9A66-0CF944B2D8C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).